Surgical pathology report (de-identified scan), TCGA case TCGA-F2-A7TX, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site UNC, specimen TCGA-F2-A7TX-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY

Case Number :

ICD O-3
C44F Adenocarcinoma, duct NOS
850013
path Adenocarcinoma NOS 814013

Site: Pancreas head
C25.0

9/5/14

Diagnosis:

A: Liver, right lobe, segment 4, biopsy

- Negative for malignancy
- Fragments of dense fibrous tissue and blood clot
- No definitive liver parenchyma identified

B: Falciform ligament, biopsy

- Negative for malignancy

C: Perigastric lymph node, biopsy

- One lymph node, negative for malignancy (0/1) with densely hyalinized nodule with dystrophic calcifications (see comment)

D: Common bile duct, margin

- Fragment of common bile duct with rare atypical cells suspicious for invasive adenocarcinoma
- See comment

E: Pancreatic duct, margin

- Negative for malignancy

F: Gallbladder, cholecystectomy

- Severe acute and chronic cholecystitis with mucosal erosion and reactive atypia
- Negative for malignancy

G: Explanted biliary stent

- Surgical mesh consistent with biliary stent placement
- Necrotic debris with scant fragments of atypical bile duct epithelium consistent with high grade dysplasia (PanIN-3)

H: Pancreas, pancreaticoduodenectomy

Tumor histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor size: 3.6 cm (gross measurement)

Tumor site: Pancreatic head; tumor encases bile duct

Tumor focality: Unifocal

[page 2 of 8]
Microscopic extent of invasion:

Peripancreatic soft tissues: Positive for tumor

Duodenum: Tumor invades muscularis propria and submucosa of duodenum

Ampulla: Negative for malignancy, but extensive high grade dysplasia

Lymphovascular invasion: Present

Perineural invasion: Present

Margins:

Pancreatic resection margin: Negative for malignancy; tumor is 1.0 cm from the pancreatic resection margin

Bile duct: Positive for adenocarcinoma (H4); presumably superseded by specimen D

Uncinate process (retroperitoneal) margin: Negative for malignancy, but close; tumor is 0.1 cm from the uncinate margin

Peripancreatic soft tissues: Positive for tumor (H18)

Proximal (gastric or duodenal): Negative for malignancy; tumor is 3.0 cm from the gastric margin (gross measurement)

Distal (duodenal): Negative for malignancy; tumor is 12.0 cm from the duodenal margin (gross measurement)

Distance to closest margin (specify): Tumor extends to peripancreatic soft tissue margin and to the common bile duct margin (the latter in this specimen)

Treatment effect (if applicable):

- No prior treatment

Regional lymph nodes: 7 of 18 lymph nodes positive for metastatic poorly differentiated adenocarcinoma, 4 mm in greatest dimension, positive for extracapsular extension (7/18)

Additional pathologic findings: - Focal PanIN-2

- Extensive acute and chronic pancreatitis with ulceration of common bile duct and extension of inflammation into surrounding soft tissue

Diagnosis of other organs or structures:

- Stomach with moderate chronic gastritis with prominent intestinal metaplasia, reactive atypia and acute serositis

- No Helicobacter pylori identified on H & E stain

- Small bowel margin with acute serositis

- Numerous hyalinized soft tissue nodules with dystrophic calcifications suggestive of previous fat necrosis

[page 3 of 8]
AJCC Pathologic TNM Stage: pT3 pN1

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

I: Liver, biopsy

- Liver with cirrhosis and changes consistent with steatohepatitis
- No malignancy identified
- Prominent centrilobular cholestasis consistent with large bile duct obstruction
- Mildly increased hepatocyte iron (grade 1)
- See comment

Comment:

The findings in specimen C may represent an old calcified granuloma or possibly an area of fat necrosis.

The frozen section slides for specimen D are reviewed and the frozen section diagnosis confirmed. The atypical cells are seen only on the permanent sections for specimen D and, later, invasive carcinoma is seen in the common bile duct margin in specimen H.

Microscopic examination of specimen I demonstrates liver with cirrhosis. The dense bands of fibrosis are outlined by trichrome and reticulin stains. Prominent peri-cellular fibrosis is also present. Mildly increased hepatocyte iron is seen on iron stain in hepatocytes and portal tracts. No significant PAS positive material suggestive of alpha-1 antitrypsin deficiency seen on PASD stain, although abundant PAS-positive material is present in Kupffer cells, consistent with hepatocyte damage. There is prominent centrilobular cholestasis with feathery degeneration suggestive of large duct obstruction. There is also focal ballooning degeneration and macrovesicular steatosis involving approximately 10% of the hepatic parenchyma with prominent Mallory's hyaline. There is bile ductular proliferation with portal inflammation consisting predominantly of lymphocytes with focal interface hepatitis. Lobular inflammation consisting of neutrophils and lymphocytes is also present.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by Dr. in _____ on
at _____ (A,B) at _____ (D-E)

[page 4 of 8]
FSA1: Liver, right lobe, segment 4, biopsy
- No tumor identified (Levels x4)

FSB1: Falciform ligament, biopsy
- No tumor identified (Levels x3)

FSC1: Perigastric lymph node, biopsy
- No tumor identified

FSD1: Common bile duct, margin
- Focal atypical epithelium in a background of severe acute and chronic inflammation, favor reactive
- Dr. concurs

FSE1: Pancreatic duct margin, biopsy
- No tumor seen

Drs. at _____ on _____ (A,B) and _____ (C); and
Drs. at _____ (D-E).

Frozen Section Pathologist:, MD

Clinical History:

-year-old male with pancreatic mass. FNA was positive for adenocarcinoma.

Gross Description:

Received are nine appropriately labeled containers. Specimens A-E are received fresh for frozen section.

Container A is additionally labeled "biopsy, liver, right lobe." It consists of multiple fragments of red/tan soft tissue and blood with an aggregate measurement of 0.3 x 0.1 x 0.1 cm in aggregate. (Block FSA1,

Container B is additionally labeled "biopsy, falciform ligament." It consists of a 0.1 x less than 0.1 x less than 0.1 cm white/tan soft tissue fragment totally submitted as FSB1,

Specimen C is additionally labeled "perigastric lymph node" and consists of a 1.3 x 1.3 x 0.7 cm pink/tan lymph node candidate which is calcified on cut surface. The specimen is trisected and completely submitted as FSC1,

[page 5 of 8]
Specimen D is additionally labeled "common bile duct" and consists of two fragments of pink/tan soft tissue, 0.8 x 0.3 x 0.3 cm in aggregate, submitted as FSD1,

Specimen E is additionally labeled "pancreatic duct margin" and consists of a 0.3 x 0.3 x 0.2 cm aggregate of pink/tan soft tissue, totally submitted as FSE1,

Specimen F is appropriately labeled "gallbladder" is a 8.7 x 2.6 x 0.9 cm gallbladder received with a 2 x 1.4 cm defect at the level of the body. Attached is a 0.5 cm long x 0.5 cm diameter cystic duct which is 3.4 cm from the defect. The serosa is tan with an extensive amount of adhesions with a roughened hepatic bed. The wall is 0.3 cm to 0.4 cm thick. The mucosa is tan-brown, velvety and containing scanty amount of hemorrhagic material.

Block Summary:

F1 - cystic duct

F2 - defect with representative gallbladder

Specimen G is appropriately labeled "explanted biliary stent" is an 8.0 cm long x 0.9 cm diameter, cylindrical wired mesh with a minimal amount of tan-brown fragments of tissue. There is also a 1.4 x 0.9 x 0.3 cm aggregate of soft, tan-brown tissue submitted entirely in block G1,

Specimen H is additionally labeled "Whipple."

Specimen fixation: formalin

Specimen type: Standard Whipple

Organs received (Whipple Specimen): Distal stomach (1.9 cm long x 3.1 cm in diameter); Duodenum (14.6 cm long x up to 5.7 cm in circumference); Pancreas (5.9 x 4.9 x 4.2 cm)

Orientation: Inking: CBD=yellow, pancreatic body margin=blue, uncinate=black, peripancreatic soft tissue=green.

Tumor location: Pancreatic head

Tumor dimensions: 3.6 x 3.2 x 2.4 cm

[page 6 of 8]
Gross appearance of tumor: Tan/gray, firm, lobulated and ill-defined.

Extent of invasion:

Confined / non-confined to the pancreas: grossly appears to be confined

Involvement of the ampulla: not involved

Involvement of the duodenum: grossly appears to involve the duodenal wall, but not the mucosa

Involvement of the bile duct: The mass encases the bile duct which appears granular, erythematous and dilated for a length of 3.4 cm.

Involvement of adjacent vessels: does not appear to grossly appear to involve

Spleen (if applicable): n/a

Gallbladder (if applicable): n/a

Stomach (if applicable): grossly does not involve

Surgical margins:

Pancreatic body: focally abuts

Uncinate (Retroperitoneal): 0.1 cm

Common Bile duct: 0.1 cm

Proximal margin (stomach): 3.0 cm

Distal margin (duodenum): 12.0 cm

Peripancreatic soft tissues: 0.1 cm

Vascular groove: 0.1 cm

Lymph nodes: Multiple lymph node candidates are grossly identified, ranging in size from 0.3 to 2.1 cm in greatest dimension.

[page 7 of 8]
Other remarkable findings: The pancreas demonstrates a 0.8 cm in greatest dimension cyst with a smooth inner lining, tan in the uncinata. The remaining pancreatic tissue is tan/yellow and lobulated with interspersed adipose tissue. The duodenal mucosa is tan/brown with normal folding pattern without any masses or lesions grossly identified. The distal stomach mucosa is tan, granular, without any masses or lesions grossly identified.

Digital photograph taken: not taken

Tissue submitted for special investigation: Tissue procured for research

Block summary:

H1 - representative proximal, en face
H2 - distal, en face
H3 - ampulla, perpendicular
H4 - common bile duct, en face
H5-H8 - pancreatic body resection margin, perpendicular sections
H9-H12 - uncinata margin, perpendicular sections
H13 - mass with respect to duodenal wall
H14-H16 - mass with respect to common bile duct and peripancreatic soft tissue (inked green)
H17 - mass involvement with duodenum with respect to pylorus
H18 - mass with respect to peripancreatic soft tissue (inked green)
H19 - representative pancreatic cyst and uninvolved pancreatic tissue
H20 - normal uninvolved pancreas
H21 - normal uninvolved duodenum
H22-H23 - multiple lymph node candidates
H24 - one bisected lymph node candidate
H25-H26 - representative remaining fibroadipose tissue

Specimen I is appropriately labeled "liver biopsy" 8.8 cm long x 0.2 cm diameter 1 cm diameter aggregate of 6 cores submitted entirely in block I1,

Per TSS, dx discrepancy form states
TCGA tumor to be adenocarcinoma,
ductal.

[page 8 of 8]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on _____) Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	adenocarcinoma, poorly differentiated	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	ductal adenocarcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Per the sign out pathologist, it was a poorly differentiated tumor but is thought to be a ductal adenocarcinoma.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 9f2fd6a5-96d7-4cae-bb58-d1a8cb8dfbbe (TCGA-F2-A7TX.DA05A8C3-0968-4405-9C62-E65B8C167AD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).